Gene-level copy-number profile of tumor specimen TCGA-CV-5436-01A from TCGA case TCGA-CV-5436, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 65.5 years (23,923 days).
Specimen TCGA-CV-5436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.2b3d31f2-ba61-41f1-9a93-34fb5c7ee07d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5436-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0c7641d0-52a1-4f5b-a5d9-26d09d14fc34

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 10,503; copy number 2: 38,741; copy number 3: 7,873; copy number 4: 1,885; copy number 5: 189; copy number 6: 255; copy number 7: 99; copy number 8: 220; copy number 10: 12; copy number 17: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5436-01A-01D-1510-01): tumor purity 0.68, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:8,341,937–8,389,183, 1 gene: AL359378.1.
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–88,049,823, 3 genes: RPL11P3, AC063965.1, MED6P1.
- chr15:67,063,763–67,195,169, 2 genes (within-gene range 0–2): SMAD3, AC012568.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 786 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:189,879,609–190,203,484, 1 gene, copy number 17 (within-gene range 1–17): C2orf88.
- chr2:190,055,700–195,026,370, 54 genes, copy number 6–17: MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2, AC096647.1, SLC44A3P1, DNAJC17P1, SEC61GP1, AC074290.1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1.
- chr4:47,914,142–48,780,322, 12 genes, copy number 10 (within-gene range 3–10): NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P.
- chr14:21,962,819–22,506,702, 75 genes, copy number 5 (broad region; genes not listed).
- chr16:54,845,189–55,506,691, 16 genes, copy number 5 (within-gene range 3–5): CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2, MTND5P34, AC109136.1, AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1.
- chr16:56,608,584–58,684,770, 98 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–6,123,030, 192 genes, copy number 6 (broad region; genes not listed).
- chr20:7,302,056–26,251,546, 338 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
